MMRF case MMRF_2330 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a949c727-3293-4448-a7f5-330f0445c9d1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.4 years (21,343 days); ISS stage: II; Days to last known disease status: 814 days (2.2 years); Days to last follow up: 814 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 74 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 88 days; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 234 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 236 days; Days to treatment end: 236 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 607 days (1.7 years); Days to treatment end: 684 days (1.9 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 607 days (1.7 years); Days to treatment end: 677 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 607 days (1.7 years); Days to treatment end: 683 days (1.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 694 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 694 days (1.9 years); Days to treatment end: 695 days (1.9 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 696 days (1.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -10 (ECOG 1): M Protein 6.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.3 mg/dL; Immunoglobulin G 82.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 3.36 µg/mL; Hemoglobin 6.14 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 34 g/L; Total Protein 12.6 g/dL; Glucose 4.84 mmol/L; C-Reactive Protein 0.038 mg/dL.
- Day 74 (ECOG 1): M Protein 1.43 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.44 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 6.71 mmol/L.
- Day 180 (ECOG 1): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.232 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 5.55 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 264 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.963 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.3 g/dL; Glucose 5.12 mmol/L.
- Day 361 (ECOG 1): M Protein 0.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.543 mg/dL; Immunoglobulin G 8.76 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.42 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.79 mmol/L.
- Day 432 (ECOG 1): M Protein 0.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.17 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 568 (ECOG 1): M Protein 0.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 7.07 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.6 g/dL; Glucose 4.95 mmol/L.
- Day 641 (ECOG 1): M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.821 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 6.49 mmol/L.
- Day 709 (ECOG 1): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.91 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.939 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 8.09 mmol/L.
- Day 814 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 7 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 5.9 g/dL; Glucose 3.85 mmol/L.

Other clinical attributes
- Day -10: Weight: 77 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples)
- Sample MMRF_2330_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -10 days.
- Sample MMRF_2330_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -10 days.
- Sample MMRF_2330_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 641 days (1.8 years).
